CCDI case PBCASS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6dc61c25-e3de-4048-af52-f6dd57dcd55d

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Mesenchymal chondrosarcoma: ICD-O-3 morphology code: 9240/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 15.9 years (5,793 days).

Biospecimens (2 samples)
- Sample 0DN51L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DN525: Tissue type: Tumor; Specimen type: Solid Tissue.
